CCDI case PBCHMZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4721dec1-f3ba-4407-aacf-594fe3c7c561

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 0.3 years (93 days).

Biospecimens (3 samples)
- Sample 0DSTY0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSTY6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSTYB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
